FM case AD2878 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/9da4626e-717e-4fcc-a22b-91eb62bd6b1f

Female, 49.4 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the fallopian tube. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
